Somatic mutation profile of tumor specimen TCGA-YL-A8HO-01A (aliquot TCGA-YL-A8HO-01A-11D-A364-08) from TCGA case TCGA-YL-A8HO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.1 years (24,509 days).
Specimen TCGA-YL-A8HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f54f1c1b-45f4-439e-a17d-1f12047010a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8HO-10A (Blood Derived Normal), aliquot TCGA-YL-A8HO-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe5711ed-b8b7-45e1-98ee-c3e160ad2847

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 3, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.3808C>T p.R1270* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs575627531, CM095220, COSV66072346; called by muse, varscan2
- APBB2 | c.1684T>C p.S562P (on ENST00000295974 / NM_001166050.2; = p.S563P on NM_004307.2) | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as COSV99923416; called by muse, mutect2
- C11orf42 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99792196; called by muse, mutect2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs780657010; called by mutect2, varscan2
- CKAP2L | c.561C>A p.N187K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV56695549; called by muse, mutect2, varscan2
- CTPS2 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100826925; called by muse, mutect2, varscan2
- CYP2C19 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100990553, COSV64907071; called by muse, mutect2
- DDX3Y | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100267560; called by muse, mutect2, varscan2
- EPB41L5 | c.896T>G p.F299C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758866; called by muse, mutect2, varscan2
- FAM120A | c.1816C>G p.R606G | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52901533; called by muse, mutect2
- FZD7 | c.217C>G p.H73D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99637280; called by muse, mutect2, varscan2
- H2AC8 | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99773275; called by muse, mutect2, varscan2
- IGF1R | c.2675A>C p.K892T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV99152248; called by muse, mutect2, varscan2
- KPNA1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as rs1298649358, COSV100724263; called by muse, mutect2, varscan2
- MARCHF1 | c.337C>A p.Q113K (on ENST00000274056; = p.Q96K on NM_017923.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV56815098, COSV99921534; called by muse, varscan2
- MXRA5 | c.3154G>A p.D1052N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV99477685; called by muse, mutect2, varscan2
- NEDD4 | c.3641A>G p.K1214R (on ENST00000508342 / NM_001284338.1; = p.K795R on NM_006154.4) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.502); catalogued as COSV100163853; called by muse, mutect2
- NRXN3 | c.1801G>T p.A601S (on ENST00000335750 / NM_001330195.2; = p.A228S on NM_004796.6) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100205208; called by muse, mutect2
- SIPA1L1 | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as rs1428925395, COSV100665685; called by muse, mutect2
- SLC24A1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371550495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STT3A | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV101205214; called by muse, mutect2
- ZSCAN25 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99500610; called by muse, mutect2
- MUC5B | c.11194A>T p.T3732S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- NEURL4 | c.1970_1971del p.Q657Rfs*37 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- BDNF | c.528A>G p.Q176= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV100151640; called by muse, mutect2
- GBP4 | c.384G>A p.S128= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs768351437, COSV63254759; called by muse, mutect2, varscan2
- PCDH12 | c.2460G>A p.P820= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs748934043, COSV99186590; called by mutect2, varscan2
- REC8 | c.213C>T p.A71= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV61015893; called by muse, mutect2, varscan2
- RIMS3 | c.405C>T p.S135= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs371406864; called by muse, mutect2
- SHD | c.306C>T p.A102= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs111528734, COSV101619055; called by muse, mutect2, varscan2
- TRIM28 | c.1710G>A p.E570= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs373664048; called by muse, mutect2, varscan2
- ZNF516 | c.2094A>T p.G698= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101487308; called by muse, mutect2, varscan2
- ADRA1A | chr8:26766096 A>G | 3'Flank (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99371343; called by muse, mutect2, varscan2
